Surgical pathology report (de-identified scan), TCGA case TCGA-77-7465, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7465-01A (Primary Tumor).

[page 1 of 2]
HISTORY

R upper lobectomy for SCC.

MACROSCOPIC

Three specimens received

1: The specimen is labelled 'right upper lobe' and consists of a lobectomy specimen measuring 140 x 120 x 75 mm in its partially inflated state. Two bronchi are present at the margin measuring 10 to 12 mm in diameter respectively. Two staple lines are also present radiating from the bronchial margin to the periphery. They measure 35 and 80 mm in length. A large lymph node is present adjacent to the bronchial resection margin. The cut surface of the lung shows a central lobulated tumour measuring 39 x 32 x 30 mm. The cut surface has areas of necrosis and carbon pigment. It appears to overrun several central peribronchial lymph nodes. Numerous smaller non-involved peribronchial lymph nodes are also identified. Tumour compresses one of the main bronchi towards the hilum. It lies approximately 10 mm from the bronchial margin and appears clear of the soft tissue margin. It is 5 mm from the nearest pleural surface. The distal lung shows evidence of collapse, consolidation and bronchiectasis. There also areas of parenchymal haemorrhage, likely iatrogenic. Two 1 to 2 mm tan nodules are seen within the collapsed zone, distal to the tumour. There are also two firm granular areas within the lung parenchyma away from the tumour. These range in size from 4 to 5 mm in greatest dimension. The residual lung parenchyma shows mild emphysema away from the areas of collapse, however this is difficult to assess. [1A, bronchial resection margin; 1B-1C, one peribronchial lymph node bisected; 1D-1F, RS tumour and adjacent main bronchus; 1G, RS tumour and closest pleural surface; 1H, peribronchial lymph nodes; 1I, RS lung parenchyma distal to tumour; 1J, RS two small nodules distal to tumour; 1K, RS lung parenchyma away from tumour; 1L, two firm granular lesions.]

2: The specimen is labelled 'number 4 lymph node' and consists of a grey to black piece of soft tissue consistent with a node measuring 15 mm in greatest dimension. The node has a black to white cut surface. [Trisected, BIT, 2A.]

3: The specimen is labelled 'number 5 right side lymph node' and consists of a grey piece of soft tissue consistent with a lymph node measuring 28 mm in greatest dimension. The cut surface contains numerous white nodules. [Trisected, BIT, 3A-3B.]

MICROSCOPIC

1: Sections show a moderately to poorly differentiated squamous cell carcinoma which appears to arise from a segmental bronchus close to the hilum and which obliterates several segmental bronchi. Tumour involves peribronchial fat at the hilum but appears clear of the surgical resection margin. The bronchial resection margin shows no evidence of squamous metaplasia or dysplasia. Tumour directly invades and appears to replace at least one peribronchial lymph node. A number of silicotic nodules are present within other peribronchial lymph nodes. Several foci of vascular invasion are present, including involvement of a major branch of the pulmonary artery which contains tumour within its lumen. Definite lymphatic or perineural invasion is not identified. Distant lung parenchyma contains dust macules and fibromuscular

[page 2 of 2]
scars and shows severe emphysema. There are also vascular changes in keeping with organised thrombi distal to the tumour.

2 & 3: Sections show anthracotic lymph nodes containing a few small silicotic nodules but no evidence of metastatic carcinoma.

SUMMARY

Right upper lobectomy, no. 4 and no. 5 lymph nodes:

Squamous cell carcinoma, 39 mm in diameter.

Vascular invasion present.

No pleural, lymphatic or perineural invasion identified.

Direct invasion of peribronchial lymph node.

Pathological stage T2a N1.

T-28000 M-80703 P1-03000

cc: Lung Cancer Registry

Source: NCI Genomic Data Commons file 3330510b-1b68-44d9-9eb4-9d90ee8c7672 (TCGA-77-7465.260A21C6-7973-461C-B4CC-4AA32AD318F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).